Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A1Q0, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A1Q0-01A (Primary Tumor).

Project #
TSS

ICD-0-3

Melanoma, NOS 8720/3

Site: Skin, NOS C44.9 3/12/11 *hw*

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format
1				Caucasian (White)	Melanoma		Female		Skin	Primary	Tumor	Tissue	Frozen
				Caucasian (White)	Melanoma		Female		Blood	n/a	normal	Blood	Frozen
Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation	Cellular Tumor %
cryomold	1	200	mg	Surgery	Melanoma	n/a	4	0	0	no	no	no	70
tube	1	4	ml	Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no	n/a

WHO Discrepancy		☒

3/12/11 *hw*

Source: NCI Genomic Data Commons file 34467a38-6684-4c8c-af02-fd341729ab27 (TCGA-BF-A1Q0.F66E3F2C-AC43-499A-82AD-D5FBC76A154B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).